Somatic mutation profile of tumor specimen TCGA-DX-A8BN-01A (aliquot TCGA-DX-A8BN-01A-11D-A37C-09) from TCGA case TCGA-DX-A8BN, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 78.7 years (28,760 days).
Specimen TCGA-DX-A8BN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14fecf49-1558-47ce-8139-062e497d7da7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BN-11A (Solid Tissue Normal), aliquot TCGA-DX-A8BN-11A-22D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/374dfd92-7aae-48d7-a634-f9179520759a

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, Frame Shift Del 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC131160.1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766014244, COSV100226204; called by muse, mutect2, varscan2
- ACTL9 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs781910740, COSV61006476; called by muse, mutect2, varscan2
- ANGEL2 | c.1493T>C p.V498A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as COSV100853955; called by muse, mutect2, varscan2
- ATRX | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV64874680; called by muse, mutect2, varscan2
- CACNG8 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as COSV99555004; called by muse, mutect2, varscan2
- CCDC22 | c.1768C>A p.Q590K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100873165; called by muse, mutect2, varscan2
- CFAP299 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs142731425; called by muse, mutect2, varscan2
- FANCB | c.2014A>T p.M672L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV100146553; called by muse, mutect2, varscan2
- FXR2 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1350974522, COSV100002077; called by muse, mutect2, varscan2
- IL2RG | c.795C>G p.I265M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52149704, COSV99340216; called by muse, mutect2, varscan2
- KRTAP5-5 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV101294177; called by muse, mutect2, varscan2
- LGALS14 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1470376868, COSV100648439; called by muse, mutect2
- MARK1 | c.889A>T p.I297L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100857260; called by muse, mutect2
- MTHFSD | c.502A>T p.M168L (on ENST00000360900 / NM_001159377.2; = p.M167L on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV100530404; called by muse, varscan2
- MYO1E | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55681989, COSV99895595; called by muse, mutect2, varscan2
- PAPOLB | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs1221809689, COSV101271423; called by muse, mutect2, varscan2
- PEX5L | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55844802; called by muse, mutect2, varscan2
- PPP2R3A | c.2813G>T p.R938M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99387209; called by muse, mutect2, varscan2
- PYGM | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99377130; called by muse, mutect2, varscan2
- SERPINF2 | c.1462G>A p.G488S | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV100131940; called by muse, varscan2
- SHANK2 | c.3622C>T p.R1208W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99574097; called by muse, mutect2, varscan2
- SND1 | c.2090A>C p.Y697S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.88); catalogued as COSV100690411, COSV61249008; called by muse, mutect2, varscan2
- TMTC3 | c.2415del p.E805Dfs*7 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as COSV99898008; called by mutect2, pindel
- TNXB | c.9061G>A p.D3021N (on ENST00000647633; = p.D2774N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/105 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV100926337; called by muse, mutect2, varscan2
- TRPV6 | c.1669C>A p.P557T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV100844308; called by muse, mutect2, varscan2
- UBOX5 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV99417941; called by muse, mutect2
- XKR4 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as rs1234090612, COSV100531660, COSV59302767; called by muse, mutect2, varscan2
- ZNF430 | c.267G>C p.E89D | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs759422741, COSV55109013, COSV99841796; called by muse, mutect2, varscan2
- ABCB10 | c.1416G>A p.E472= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs1326621554, COSV100747959; called by muse, mutect2, varscan2
- IGDCC3 | c.480C>T p.C160= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100031146; called by muse, mutect2, varscan2
- INTS5 | c.2065C>T p.L689= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100399625; called by muse, mutect2, varscan2
- MAMDC4 | c.1506C>T p.G502= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99915666; called by muse, mutect2
- NRP2 | c.693G>T p.G231= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99784546; called by muse, mutect2, varscan2
- P2RX2 | c.987G>A p.V329= (on ENST00000343948 / NM_170683.4; = p.V257= on NM_012226.5) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1367761579, COSV100266769; called by muse, mutect2, varscan2
- WDR81 | c.3810C>T p.G1270= (on ENST00000409644 / NM_001163809.2; = p.G219= on NM_152348.4) | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs762351080, COSV100488863; called by muse, mutect2, varscan2
- TIMM50 | chr19:39480783 T>A | 5'Flank (SNP) | VAF 27/236 reads (11%) | catalogued as COSV100067929; called by muse, mutect2, varscan2
